Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A1KW, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A1KW-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: Gastric & Mixed Tumo
Account #: [REDACTED] Date of Procedure:
DOB: [REDACTED] Date of Receipt:
Physician: [REDACTED]
CC: [REDACTED]

....

Specimens Submitted:

1: SP: Right retroperitoneal mass, right colon, right diaphragm

DIAGNOSIS:

1. RIGHT COLON, TERMINAL ILEUM, RIGHT DIAPHRAGM AND RIGHT RETROPERITONEAL MASS, WIDE EXCISION AND SEGMENTAL COLECTOMY:
- HIGH GRADE DEDIFFERENTIATED LIPOSARCOMA (24.5 X 18.0 X 11.0 CM), ADHERENT TO THE DIAPHRAGM SKELETAL MUSCLE AND BOWEL WALL.
- THE DEDIFFERENTIATED COMPONENT PREDOMINATES (>50% OF THE MASS) AND HAS A HIGH GRADE FIBROSARCOMA/MALIGNANT FIBROUS HISTIOCYTOMA-LIKE APPEARANCE.
- AREA OF NECROSIS ARE PRESENT, ESTIMATED GROSSLY AS 10%.
- TUMOR IS SURROUNDED BY THIN INTACT MEMBRANE. HOWEVER, MICROSCOPICALLY TUMOR EXTENDS TO INKED SURFACE.
- UNREMARKABLE BOWEL SEGMENT.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh, labeled "right retroperitoneal mass, right colon, right diaphragm" and consists of a 24.5 x 18 x 11 cm mass with a portion of terminal ileum (13 x 3.8 cm), cecum, colon (19 x 8 cm), mesentery (1.5 to 4.5 cm in thickness), and an appendix (6.5 x 0.5 x 0.4 cm). A portion of possible diaphragm measuring 5 x 1.5 x 0.3 cm is identified on the opposite side of the colon. Grossly the mass is covered by peritoneal membrane and fibrous membrane measuring 0.1 cm in thickness, on all the aspects except inferior aspect, which is covered by fatty tissue. The mass pushes the diaphragm, peritoneum and is 2.5 cm from colonic mucosa. The cut surface of the mass is yellow-tan and lobulated with firmer areas of possible necrosis (approximately 10% of the tumor), hemorrhage mixed with

** Continued on next page **

1CD-0-3
dedifferentiated liposarcoma 8858/3
Site: Retroperitoneum C48.0
2/21/11
pw

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

MRN: [REDACTED]

Account #: [REDACTED]

Accession #: [REDACTED]

Physician: [REDACTED]

Service: Gastric & Mixed Tumo [REDACTED]

Page 2 of 2

myxoid areas. The external surface of the specimen is inked black. TPS is taken.

Sections:

App appendix

Bm- bowel margins

Rsb- representative sections of the bowel.

Td tumor with diaphragm

Tm- tumor with margins

Tp- tumor with peritoneum.

T tumor, representative sections

Summary of Sections:

Part 1: SP: Right retroperitoneal mass, right colon, right diaphragm

Block	Sect.	Site	PCs
1	app		1
1	bm		2
2	rsb		2
15	t		15
1	td		1
4	tm		4
1	tp		1

**** End of Report ****

Reviewer Initials: [Signature] Date Reviewed: [Date]		

Source: NCI Genomic Data Commons file 7addf118-505f-4b4c-b280-30a9626cbf17 (TCGA-DX-A1KW.70A91A22-B1CD-4EA1-966B-DB28A652720C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).